Somatic mutation profile of tumor specimen TCGA-EE-A2GT-06A (aliquot TCGA-EE-A2GT-06A-12D-A197-08) from TCGA case TCGA-EE-A2GT, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 78.5 years (28,665 days).
Specimen TCGA-EE-A2GT-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b8d8fea-96d2-45a9-b435-8b920ce006d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2GT-10A (Blood Derived Normal), aliquot TCGA-EE-A2GT-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0eee50e2-ab86-4f36-b197-2b4cf1e7eb91

The open-access MAF lists 393 somatic variants for this specimen: 248 protein-altering or splice-affecting, 135 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 220, Silent 135, Nonsense Mutation 20, Intron 3, Frame Shift Ins 3, 3'UTR 3, RNA 3, Splice Site 3, Splice Region 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.5572C>T p.R1858* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as rs1270783041, COSV57335311, COSV57381817; ClinVar: pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSM2B | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61657522; called by muse, mutect2, varscan2
- ADCY7 | c.1596-1G>A p.X532_splice | Splice Site (SNP) | VAF 24/133 reads (18%) | catalogued as COSV99575746; called by muse, mutect2, varscan2
- ADGRB1 | c.3975C>G p.I1325M | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as COSV60100784; called by muse, mutect2, varscan2
- AHCY | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.816); catalogued as rs1442052232, COSV54153822; called by muse, mutect2, varscan2
- AMPH | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100341855, COSV57750213; called by muse, mutect2, varscan2
- AMY2B | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 44/360 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs368462934; called by muse, varscan2
- APCDD1L | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as COSV64487256; called by muse, mutect2, varscan2
- APOB | c.13423G>A p.E4475K | Missense Mutation (SNP) | VAF 115/618 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51942169; called by muse, mutect2, varscan2
- AQP6 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV59646001; called by mutect2, varscan2
- AQP7 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV53025026; called by muse, varscan2
- ASAP3 | c.2171G>A p.G724E | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.235); catalogued as rs1558105763, COSV60876438; called by muse, mutect2, varscan2
- ASXL3 | c.1916C>T p.S639L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); catalogued as rs950356298; called by mutect2, varscan2
- ATG4C | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as rs41305874, COSV58604286; called by mutect2, varscan2
- ATP5PB | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV52385809; called by mutect2, varscan2
- ATR | c.3068T>C p.V1023A | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV63389031; called by muse, mutect2, varscan2
- BICRAL | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 80/288 reads (28%) | catalogued as COSV58407366; called by mutect2, varscan2
- BOLL | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56574290, COSV56575790; called by muse, mutect2, varscan2
- BRWD1 | c.854C>G p.S285C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100313645, COSV60899926; called by muse, mutect2, varscan2
- BTBD7 | c.2525C>T p.A842V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.057); catalogued as rs768880925, COSV58288833; called by mutect2, varscan2
- C10orf71 | c.1646A>G p.E549G | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV60510371; called by muse, mutect2, varscan2
- C12orf42 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV59387239; called by mutect2, varscan2
- C3orf56 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.819); catalogued as COSV67756394; called by muse, mutect2, varscan2
- C8A | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV63483594; called by muse, mutect2, varscan2
- CARD16 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV65213221; called by muse, mutect2, varscan2
- CARF | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 125/534 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV57548877; called by muse, mutect2, varscan2
- CCNB3 | c.2068T>C p.F690L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.113); catalogued as rs782200903, COSV52077025; called by muse, mutect2, varscan2
- CD163 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 58/307 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63135368; called by muse, mutect2, varscan2
- CD2AP | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 30/137 reads (22%) | catalogued as COSV63761831, COSV63763022; called by mutect2, varscan2
- CD48 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as COSV63567250; called by muse, mutect2, varscan2
- CD5L | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs545632901, COSV63822637; called by mutect2, varscan2
- CDCA5 | c.243+2T>G p.X81_splice | Splice Site (SNP) | VAF 15/52 reads (29%) | catalogued as COSV51870289; called by muse, varscan2
- CDH6 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54074558; called by muse, mutect2, varscan2
- CENPI | c.2234C>T p.P745L | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV54504476; called by muse, mutect2, varscan2
- CFAP52 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55343795; called by muse, mutect2, varscan2
- CHAF1A | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as COSV56674764; called by muse, mutect2, varscan2
- CHD1 | c.1038G>T p.M346I | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV52342802; called by muse, mutect2, varscan2
- CLCNKB | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as rs539214175, COSV65161271; called by mutect2, varscan2
- CLDN11 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as COSV50355802; called by muse, mutect2, varscan2
- CMKLR1 | c.484G>A p.V162I (on ENST00000312143 / NM_001142344.2; = p.V160I on NM_004072.3) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.014); catalogued as COSV56440551; called by muse, mutect2, varscan2
- COL1A2 | c.2317C>T p.P773S | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.112); catalogued as COSV51962317; called by muse, mutect2, varscan2
- COL4A4 | c.3469G>A p.G1157R | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61634468; called by muse, mutect2, varscan2
- COL4A5 | c.1625G>A p.G542E | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60366928, COSV60375553; called by muse, mutect2, varscan2
- CPT1C | c.1551G>A p.W517* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV54920949; called by muse, mutect2, varscan2
- CSMD3 | c.9616G>A p.E3206K (on ENST00000297405 / NM_001363185.1; = p.E3037K on NM_052900.3) | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV52252760; called by muse, mutect2, varscan2
- CSNK1G2 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs959347436, COSV99730056; called by mutect2, varscan2
- CTSE | c.1183G>A p.G395R (on ENST00000360218; = p.G390R on NM_001910.4) | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63060072; called by muse, mutect2, varscan2
- CUZD1 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV59027436; called by muse, mutect2, varscan2
- CYLC2 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs369079750; called by mutect2, varscan2
- CYP19A1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1485079207, COSV53058893; called by muse, mutect2, varscan2
- CYP2C19 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.022); catalogued as COSV64907127; called by muse, varscan2
- DDR2 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs771747956, COSV63372658; called by muse, mutect2, varscan2
- DDR2 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs1261100286, COSV100906925, COSV63372663; called by mutect2, varscan2
- DIP2A | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs374875312, COSV59479015; called by muse, mutect2, varscan2
- DMGDH | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs549034649, COSV54862758, COSV54866558; called by mutect2, varscan2
- DNAH12 | c.569A>C p.H190P | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV60857950; called by muse, mutect2, varscan2
- DNAH5 | c.10129G>A p.E3377K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1296283240, COSV54208350, COSV54212780; called by muse, mutect2, varscan2
- DNAH6 | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1373965792, COSV52857094, COSV52873130; called by mutect2, varscan2
- DOCK3 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV56536705; called by mutect2, varscan2
- DSCAM | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs367690354, COSV68648441; called by mutect2, varscan2
- DSG4 | c.3004C>T p.Q1002* | Nonsense Mutation (SNP) | VAF 26/112 reads (23%) | catalogued as rs267605160, COSV57394716; called by mutect2, varscan2
- DYSF | c.3823G>A p.E1275K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV50494188; called by mutect2, varscan2
- EIF3D | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as COSV53404406; called by muse, mutect2, varscan2
- ELMOD1 | c.712A>G p.I238V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); catalogued as rs1166525245, COSV56194415; called by muse, mutect2
- EMC10 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1416371327, COSV58542783; called by muse, mutect2, varscan2
- EPB41L4B | c.1887G>C p.K629N | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as COSV101000930, COSV65804315; called by muse, mutect2, varscan2
- ETV1 | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54141028; called by muse, mutect2, varscan2
- FAM171A1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV65317910; called by muse, varscan2
- FAM171A1 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs757735986, COSV65317917; called by mutect2, varscan2
- FCHSD2 | c.1936T>C p.S646P | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV60812633; called by muse, mutect2, varscan2
- FCN2 | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV52477935; called by muse, mutect2, varscan2
- FES | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs750047865, COSV51578282; called by mutect2, varscan2
- FGFR2 | c.2396C>T p.S799F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV60653984; called by muse, mutect2, varscan2
- FLG | c.2663G>A p.G888E | Missense Mutation (SNP) | VAF 61/300 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.428); catalogued as COSV64245104; called by muse, varscan2
- FPR1 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59053012; called by muse, mutect2, varscan2
- GABRA4 | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.161); catalogued as COSV51931845; called by muse, mutect2, varscan2
- GFUS | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71254345; called by mutect2, varscan2
- GIMAP2 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372328919; called by muse, mutect2, varscan2
- GLI2 | c.3124G>A p.D1042N (on ENST00000361492 / NM_001374353.1; = p.D1059N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as rs762818312, COSV58038867; called by mutect2, varscan2
- GPR32 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.061); catalogued as COSV54514671, COSV54515120; called by muse, varscan2
- GUF1 | c.1160C>T p.T387I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV55783916; called by muse, mutect2, varscan2
- HADHA | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as rs1217723921, COSV66108182; called by muse, mutect2, varscan2
- HAS1 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55788660; called by muse, mutect2, varscan2
- HOXC11 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV54533724; called by muse, mutect2, varscan2
- HSF1 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.076); catalogued as rs782416863, COSV100184230, COSV60048831; called by muse, mutect2, varscan2
- HTR3B | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52746435; called by muse, mutect2, varscan2
- HYDIN | c.9268G>A p.G3090R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.878); catalogued as COSV59264081; called by muse, mutect2, varscan2
- IFNA21 | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.308); catalogued as rs755489242, COSV66518620; called by muse, mutect2, varscan2
- IFNE | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs377000588; called by muse, mutect2, varscan2
- IL17A | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as rs1235568790, COSV60685101; called by muse, varscan2
- IL31RA | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.013); catalogued as COSV51683459; called by mutect2, varscan2
- IRF6 | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as CM092350, COSV65419897; called by muse, varscan2
- KCNA1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs1565433107, COSV66838153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNH4 | c.1488G>C p.K496N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV52915975, COSV52919751; called by muse, mutect2, varscan2
- KIAA1549 | c.1481C>T p.S494F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54321830; called by muse, mutect2, varscan2
- KLK3 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs368127664; called by mutect2, varscan2
- KPNA5 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100706452, COSV62653567; called by muse, mutect2, varscan2
- KRTAP10-1 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV59962683; called by muse, mutect2, varscan2
- KRTAP19-7 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58366581, COSV58366619; called by mutect2, varscan2
- LAMA2 | c.4036G>A p.G1346R | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763552119, COSV70337358; called by muse, mutect2, varscan2
- LGALS9 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56350065; called by muse, mutect2, varscan2
- LHX9 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); catalogued as COSV61330295; called by muse, mutect2, varscan2
- LRRC23 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV50392263; called by muse, mutect2, varscan2
- LRRC7 | c.4125A>C p.Q1375H (on ENST00000651989 / NM_001370785.2; = p.Q1295H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV50526053; called by muse, mutect2, varscan2
- LRRN1 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1483457472, COSV60014872; called by muse, mutect2, varscan2
- LRRN1 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as rs866289196, COSV60015126; called by muse, mutect2, varscan2
- LRRN2 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs148739326; called by muse, mutect2, varscan2
- LTBP2 | c.4973G>A p.G1658D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV56211312; called by mutect2, varscan2
- MAGEA4 | c.483G>A p.M161I | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV52341237; called by mutect2, varscan2
- MAOB | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs12850496, COSV65206276; called by mutect2, varscan2
- MATN3 | c.988C>T p.H330Y | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.811); catalogued as COSV68100306, COSV68100753; called by mutect2, varscan2
- MCF2L2 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61057382; called by muse, mutect2, varscan2
- MEGF8 | c.2081C>T p.T694I | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs201674841, COSV52094102; called by muse, mutect2, varscan2
- METTL18 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1180349107, COSV53681122; called by muse, mutect2, varscan2
- MLH3 | c.3946C>T p.L1316F (on ENST00000355774 / NM_001040108.2; = p.L1292F on NM_014381.3) | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53157202; called by muse, varscan2
- MMP26 | c.556C>T p.H186Y | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56173253; called by muse, mutect2, varscan2
- MROH7 | c.3347G>A p.R1116Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as rs372811123; called by mutect2, varscan2
- MUC16 | c.27640A>G p.T9214A | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV67480281; called by muse, mutect2, varscan2
- MUC16 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.197); catalogued as rs769571404, COSV67446414; called by mutect2, varscan2
- MUSK | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.523); catalogued as rs193019632, COSV51891274; called by muse, mutect2, varscan2
- MYH1 | c.4033G>A p.D1345N | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56853235; called by mutect2, varscan2
- MYH14 | c.2358C>A p.F786L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51825392; called by mutect2, varscan2
- NAT2 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as COSV54062046; called by muse, mutect2, varscan2
- NCF4 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs560705177, COSV50625043; called by mutect2, varscan2
- NEXMIF | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747436946, COSV50021850; called by mutect2, varscan2
- NFE2L3 | c.1571G>A p.R524K | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1000778681; called by mutect2, varscan2
- NKAIN2 | c.75A>C p.Q25H | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63676837; called by muse, mutect2, varscan2
- NLRP11 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as rs141337326; called by mutect2, varscan2
- NLRP2 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1392839713, COSV54757852; called by muse, mutect2, varscan2
- NLRP4 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56719024; called by muse, mutect2, varscan2
- NPR2 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV61313094; called by muse, mutect2, varscan2
- NUP214 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63911508; called by muse, mutect2, varscan2
- NUP58 | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as COSV67751742; called by mutect2, varscan2
- OR10H1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58472433; called by muse, mutect2, varscan2
- OR12D2 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs1562968360, COSV65828585; called by muse, mutect2, varscan2
- OR1L1 | c.164A>C p.N55T (on ENST00000373686; = p.N5T on NM_001005236.3) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV58936099; called by muse, varscan2
- OR4C13 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs141161603, COSV73648841; called by mutect2, varscan2
- OR51I2 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV58299525; called by muse, mutect2, varscan2
- OR51I2 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1244327018, COSV58299534; called by muse, mutect2, varscan2
- OR51L1 | c.12G>A p.W4* | Nonsense Mutation (SNP) | VAF 27/114 reads (24%) | catalogued as COSV58625290; called by muse, mutect2, varscan2
- OR51V1 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58315887; called by muse, mutect2, varscan2
- OR52N4 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV57890290; called by muse, mutect2, varscan2
- OR56A3 | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 53/208 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61569689; called by muse, mutect2, varscan2
- OR7D2 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.104); catalogued as COSV60140630; called by muse, mutect2, varscan2
- OR8G5 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.329); catalogued as COSV58380440; called by muse, mutect2, varscan2
- OR8H2 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV57946472; called by muse, mutect2, varscan2
- P4HA2 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs201043216, COSV51323838; called by mutect2, varscan2
- PAPPA2 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.053); catalogued as COSV62782379; called by muse, mutect2, varscan2
- PARP15 | c.865G>T p.V289F (on ENST00000464300 / NM_001113523.3; = p.V55F on NM_152615.2) | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV59973680; called by muse, varscan2
- PCDH15 | c.4888C>T p.R1630* (on ENST00000644397 / NM_001354429.2; = p.R1572* on NM_001142771.2) | Nonsense Mutation (SNP) | VAF 17/94 reads (18%) | catalogued as rs185389206, COSV64681842; called by mutect2, varscan2
- PCDH15 | c.5477C>T p.P1826L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV57265772, COSV57299781; called by muse, mutect2
- PCLO | c.12692C>T p.S4231F | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV61615595; called by muse, mutect2, varscan2
- PDP2 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV61240966; called by muse, mutect2, varscan2
- PDZD7 | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV56520866; called by muse, mutect2, varscan2
- PFKFB1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | PolyPhen probably damaging (0.997); catalogued as COSV66628944, COSV66628947; called by mutect2, varscan2
- PID1 | c.392C>T p.P131L (on ENST00000354069 / NM_001330156.1; = p.P129L on NM_017933.5) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as rs200100687, COSV62473176; called by muse, mutect2, varscan2
- PIGR | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62904619; called by muse, mutect2, varscan2
- PLA2G2D | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV64281822, COSV64282117; called by muse, mutect2, varscan2
- PRAMEF10 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs201689660; called by muse, mutect2, varscan2
- PTPN3 | c.1460G>A p.G487E | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as COSV52708610; called by muse, mutect2, varscan2
- PTPRT | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs751487270, COSV61957916, COSV61990404; called by muse, mutect2, varscan2
- PYHIN1 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV63721229; called by muse, mutect2, varscan2
- RABL3 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs866654963, COSV56336955; called by muse, mutect2, varscan2
- RAD51AP2 | c.3178G>A p.E1060K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as COSV67588620; called by muse, mutect2, varscan2
- RBM42 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52898482; called by muse, mutect2, varscan2
- RERE | c.3817C>T p.P1273S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (1); catalogued as COSV61946486; called by muse, mutect2, varscan2
- RIT2 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.867); catalogued as rs1401934850, COSV56297558, COSV56304514; called by muse, mutect2, varscan2
- RNF152 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.247); catalogued as COSV57186959; called by muse, mutect2, varscan2
- RRP36 | c.604C>G p.Q202E | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.119); catalogued as COSV55065141; called by muse, mutect2, varscan2
- RXFP2 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs150335466; called by mutect2, varscan2
- RYR1 | c.9458G>A p.G3153E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62093034; called by muse, mutect2, varscan2
- RYR2 | c.5959C>T p.P1987S | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as COSV63700204; called by muse, mutect2, varscan2
- SEC23IP | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64832364; called by muse, mutect2, varscan2
- SERPINB3 | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577782225, COSV52193003; called by muse, varscan2
- SGSM1 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as COSV68512045; called by mutect2, varscan2
- SHISAL1 | c.308G>A p.W103* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | catalogued as rs1168487950; called by muse, varscan2
- SLC17A2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 121/295 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV55350357; called by muse, mutect2, varscan2
- SLC17A6 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.066); catalogued as COSV54137048; called by mutect2, varscan2
- SLC22A14 | c.493A>T p.K165* | Nonsense Mutation (SNP) | VAF 18/98 reads (18%) | catalogued as COSV56198593; called by mutect2, varscan2
- SLC26A5 | c.1405C>T p.L469= | Splice Region (SNP) | VAF 24/92 reads (26%) | catalogued as rs891749409, COSV59704175; called by muse, mutect2, varscan2
- SLX4IP | c.224C>G p.P75R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57945633; called by muse, mutect2, varscan2
- SP140L | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.88); PolyPhen benign (0.051); catalogued as COSV54746179; called by muse, varscan2
- SPHKAP | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV60869481; called by muse, mutect2, varscan2
- SPSB1 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.408); catalogued as rs768783775, COSV60164068; called by mutect2, varscan2
- SPTA1 | c.4928G>A p.G1643E | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs369900804; called by muse, mutect2, varscan2
- SPTAN1 | c.1675C>T p.H559Y | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.781); catalogued as COSV63988609; called by mutect2, varscan2
- STAB1 | c.3775C>A p.R1259S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV58740363; called by muse, mutect2, varscan2
- SYNGR4 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs764820252, COSV61224992, COSV61225672; called by muse, mutect2, varscan2
- TAF1B | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as rs1321947878; called by mutect2, varscan2
- TBC1D3B | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs760438734; called by mutect2, varscan2
- TCHHL1 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV64286690; called by mutect2, varscan2
- TENM3 | c.2449G>A p.D817N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV69314301; called by muse, mutect2, varscan2
- TFDP2 | c.1325C>T p.S442F (on ENST00000489671 / NM_001178139.2; = p.S382F on NM_006286.5) | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as COSV57709619; called by muse, mutect2, varscan2
- TFDP3 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as rs1361706276, COSV59537879; called by mutect2, varscan2
- THBS4 | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63470218; called by muse, mutect2, varscan2
- THRB | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs368681026; ClinVar: uncertain significance; called by mutect2, varscan2
- TMEM132B | c.2158C>T p.P720S | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV54761873; called by muse, mutect2, varscan2
- TPO | c.640C>G p.Q214E | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV61106600; called by muse, mutect2, varscan2
- TPTE2 | c.784C>T p.R262* (on ENST00000400230 / NM_199254.2; = p.R185* on NM_130785.3) | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | catalogued as rs778548189, COSV55022979; called by mutect2, varscan2
- TRANK1 | c.2104G>A p.D702N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100083956, COSV57157914; called by muse, mutect2, varscan2
- TRGC1 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.888); catalogued as rs375000330; called by muse, varscan2
- TRIM27 | c.1105G>T p.G369W | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101019421, COSV65873842; called by muse, mutect2
- TRIT1 | c.1114C>T p.Q372* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV57549291; called by muse, mutect2, varscan2
- TTN | c.55843C>T p.P18615S (on ENST00000591111; = p.P11191S on NM_003319.4) | Missense Mutation (SNP) | VAF 27/163 reads (17%) | PolyPhen benign (0.036); catalogued as COSV60207928; called by muse, varscan2
- TTN | c.54028G>A p.E18010K (on ENST00000591111; = p.E10586K on NM_003319.4) | Missense Mutation (SNP) | VAF 38/138 reads (28%) | PolyPhen probably damaging (0.994); catalogued as rs1442747427, COSV60207963; called by mutect2, varscan2
- TTN | c.36919G>A p.E12307K (on ENST00000591111; = p.E4883K on NM_003319.4) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | PolyPhen probably damaging (0.915); catalogued as COSV60207998, COSV60377930; called by muse, mutect2, varscan2
- TTN | c.24244C>T p.L8082F (on ENST00000591111; = p.L7155F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | PolyPhen benign (0.326); catalogued as COSV60179516, COSV60208039; called by mutect2, varscan2
- TUT4 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.347); catalogued as COSV57110642; called by muse, mutect2, varscan2
- UBXN10 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.1); catalogued as COSV66772405; called by muse, mutect2, varscan2
- UGT3A2 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56928409, COSV56931996; called by muse, mutect2, varscan2
- UGT8 | c.160T>A p.F54I | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV60419476; called by muse, mutect2, varscan2
- UNC13C | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV52858169; called by muse, mutect2, varscan2
- VAV1 | c.673C>G p.Q225E | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV58387945; called by muse, mutect2, varscan2
- VWC2L | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as rs370205207; called by mutect2, varscan2
- WDR13 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); catalogued as COSV54332750; called by mutect2, varscan2
- XIRP2 | c.8585C>T p.S2862F (on ENST00000628543; = p.S3037F on NM_152381.6) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV54718925, COSV99740014; called by muse, mutect2, varscan2
- ZBTB7B | c.1276G>C p.G426R (on ENST00000292176; = p.G460R on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV52693958; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1921G>A p.G641S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.049); catalogued as COSV58743706; called by muse, mutect2, varscan2
- ZNF257 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs760874941, COSV71310228; called by muse, mutect2, varscan2
- ZNF365 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67925929; called by muse, mutect2, varscan2
- ZNF578 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV69737127; called by muse, mutect2, varscan2
- ZNF585A | c.1513C>T p.Q505* (on ENST00000292841 / NM_001288800.2; = p.Q450* on NM_152655.3) | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV53065699, COSV99493288; called by muse, mutect2, varscan2
- ZNF586 | c.101A>T p.E34V | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV66972577; called by mutect2, varscan2
- ZNF652 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV100755529, COSV62948051; called by muse, mutect2, varscan2
- ZNF667 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as COSV52637232; called by muse, mutect2, varscan2
- ZNF782 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs370494158; called by muse, mutect2, varscan2
- ZNF792 | c.815A>G p.H272R | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV68693917; called by muse, mutect2, varscan2
- ZNF804A | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs1455450441, COSV56451713, COSV56472084; called by mutect2, varscan2
- ZNF804A | c.3014T>G p.L1005* | Nonsense Mutation (SNP) | VAF 23/105 reads (22%) | catalogued as rs1242082822, COSV56460279, COSV56461220; called by muse, mutect2, varscan2
- AMPD3 | c.1963G>A p.G655R (on ENST00000396553 / NM_001025389.2; = p.G664R on NM_000480.3) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMPD3 | c.1964G>T p.G655V (on ENST00000396553 / NM_001025389.2; = p.G664V on NM_000480.3) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CES5A | c.725A>G p.K242R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- COL7A1 | c.7906C>T p.L2636F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- EMILIN2 | c.1081A>C p.S361R | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- IGKV2-24 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- IGKV2D-29 | c.331T>G p.Y111D | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ING3 | c.1127dup p.C376Wfs*2 | Frame Shift Ins (INS) | VAF 25/136 reads (18%) | called by mutect2, pindel, varscan2
- KIR3DL1 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KRTAP19-7 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTCH2 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- MYO1B | c.3023dup p.L1009Pfs*6 (on ENST00000304164; = p.L951Pfs*6 on NM_012223.5) | Frame Shift Ins (INS) | VAF 6/51 reads (12%) | called by mutect2, pindel, varscan2
- OR52B4 | c.120_121delinsT p.L41Ffs*44 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | called by mutect2*, pindel, varscan2*
- PLCXD1 | c.916G>C p.A306P | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, varscan2
- THSD7A | c.3079G>A p.A1027T | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.546); called by mutect2, varscan2
- VPS39 | c.475-3_476delinsT p.X159_splice (on ENST00000348544 / NM_001301138.2; = p.X148_splice on NM_015289.5) | Splice Site (DEL) | VAF 3/36 reads (8%) | called by mutect2*, pindel, varscan2*
- ZFX | c.2076_2079dup p.H694* | Frame Shift Ins (INS) | VAF 28/63 reads (44%) | called by mutect2, pindel, varscan2
- AAK1 | c.2091C>T p.P697= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs772229686, COSV68643343, COSV68645251; called by muse, mutect2, varscan2
- ABCB11 | c.3954C>T p.S1318= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs376013207; called by muse, mutect2, varscan2
- ABCB8 | c.42A>C p.P14= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV52507800; called by muse, mutect2, varscan2
- ABCC8 | c.765C>T p.I255= | Silent (SNP) | VAF 67/335 reads (20%) | catalogued as rs753335564, COSV56849772; called by mutect2, varscan2
- ACOX3 | c.1578C>T p.L526= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV62712964; called by muse, varscan2
- ADD1 | c.849A>G p.K283= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV53271888; called by muse, mutect2, varscan2
- ADGRV1 | c.7998G>A p.E2666= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV67990889; called by muse, varscan2
- AFF2 | c.2400C>T p.N800= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV53998978; called by muse, varscan2
- AGAP4 | c.1371G>A p.V457= | Silent (SNP) | VAF 16/216 reads (7%) | catalogued as rs1370153796, COSV101432618; called by muse, mutect2
- AKAP6 | c.3081C>T p.G1027= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs368446820; called by mutect2, varscan2
- ANO2 | c.795G>A p.K265= (on ENST00000356134 / NM_001278597.3; = p.K269= on NM_001278596.3) | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs763181934, COSV59034017; called by muse, mutect2, varscan2
- AP1M1 | c.786C>T p.F262= | Silent (SNP) | VAF 40/186 reads (22%) | catalogued as rs374198455; called by mutect2, varscan2
- ARHGAP44 | c.240G>A p.E80= | Silent (SNP) | VAF 39/170 reads (23%) | catalogued as COSV52396017, COSV52397508; called by muse, mutect2, varscan2
- BPIFA1 | c.630C>T p.I210= | Silent (SNP) | VAF 44/188 reads (23%) | catalogued as rs1373784339, COSV62824922; called by muse, varscan2
- BTN3A1 | c.504C>T p.S168= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV50025000; called by muse, mutect2, varscan2
- C12orf50 | c.1068G>A p.T356= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as rs201866729, COSV53895517, COSV53896910, COSV53897309; called by mutect2, varscan2
- C7 | c.1923G>A p.Q641= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV57477534; called by muse, mutect2, varscan2
- CACNA1B | c.3597G>A p.V1199= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV53138207; called by mutect2, varscan2
- CACNA1C | c.3483C>T p.F1161= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs367790910; called by mutect2, varscan2
- CACNA2D1 | c.2838C>T p.L946= (on ENST00000356253 / NM_001366867.1; = p.L934= on NM_000722.4) | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV62386154; called by mutect2, varscan2
- CAD | c.546C>T p.D182= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs561240288, COSV53029537; called by mutect2, varscan2
- CCT8L2 | c.1429C>T p.L477= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as COSV63463252; called by muse, mutect2, varscan2
- CDK18 | c.1488G>A p.G496= (on ENST00000506784 / NM_212503.3; = p.G466= on NM_002596.4) | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV63726666; called by muse, mutect2, varscan2
- CFAP44 | c.471C>T p.A157= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV55613921; called by mutect2, varscan2
- CFAP77 | c.624C>T p.I208= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV58014010; called by muse, mutect2, varscan2
- CNTNAP2 | c.1197C>T p.F399= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs754297905, COSV62223172; called by muse, mutect2, varscan2
- COL12A1 | c.7734G>A p.T2578= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs368616942, COSV100485531; called by mutect2, varscan2
- COL19A1 | c.1809G>A p.G603= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs1166499028, COSV59580165; called by muse, mutect2, varscan2
- COL4A1 | c.921C>T p.P307= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs138809869; called by muse, mutect2, varscan2
- COL4A4 | c.4422G>A p.T1474= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs750682352, COSV61633007; called by muse, mutect2, varscan2
- COL7A1 | c.7905C>T p.G2635= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- CPS1 | c.2298G>A p.L766= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV51817836, COSV99241480; called by muse, mutect2, varscan2
- CSMD3 | c.7776C>T p.V2592= (on ENST00000297405 / NM_001363185.1; = p.V2488= on NM_052900.3) | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV52252802; called by muse, mutect2, varscan2
- CSNK1G2 | c.138C>T p.F46= | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- CYP2J2 | c.987C>T p.L329= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV64606674; called by muse, varscan2
- DHFR2 | c.60C>T p.N20= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs199508022, COSV58933804; called by mutect2, varscan2
- DLEC1 | c.3951G>A p.R1317= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100342184; called by muse, mutect2, varscan2
- DNAH5 | c.10128A>G p.E3376= | Silent (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- DNAH5 | c.1419C>T p.F473= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs373172723; ClinVar: likely benign; called by mutect2, varscan2
- DNM3 | c.495G>A p.T165= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV62462831; called by mutect2, varscan2
- EBF2 | c.585G>A p.Q195= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV68779269; called by muse, mutect2, varscan2
- EDEM1 | c.1632C>T p.D544= | Silent (SNP) | VAF 8/61 reads (13%) | called by mutect2, varscan2
- ELP1 | c.3333T>C p.P1111= | Silent (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- EPHA6 | c.2502G>A p.R834= (on ENST00000389672 / NM_001080448.3; = p.R226= on NM_173655.4) | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV67576023; called by mutect2, varscan2
- EPHX3 | c.792C>T p.F264= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1424142625, COSV55656150; called by mutect2, varscan2
- ERBB3 | c.1434G>A p.T478= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs758336051, COSV57258753; called by muse, mutect2, varscan2
- EXPH5 | c.4248C>T p.S1416= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as rs766268403, COSV56205500; called by muse, mutect2, varscan2
- FSD1 | c.609G>A p.R203= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV55697858; called by mutect2, varscan2
- GAL3ST2 | c.417C>T p.I139= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs1317753985; called by muse, mutect2, varscan2
- GALT | c.405G>A p.S135= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as rs141232328; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLI2 | c.4473C>T p.P1491= (on ENST00000361492 / NM_001374353.1; = p.P1508= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs139840265; ClinVar: likely benign; called by muse, mutect2, varscan2
- GLI2 | c.4644C>T p.V1548= (on ENST00000361492 / NM_001374353.1; = p.V1565= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs202203798; called by mutect2, varscan2
- GLMP | c.1149C>T p.L383= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV55296418; called by mutect2, varscan2
- GLT1D1 | c.813G>A p.R271= (on ENST00000442111 / NM_001366889.1; = p.R191= on NM_144669.3) | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs200010255, COSV55885045; called by mutect2, varscan2
- GPRC5A | c.312C>T p.L104= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as rs746671084, COSV50008253; called by muse, mutect2, varscan2
- GRIA1 | c.732G>A p.K244= | Silent (SNP) | VAF 49/176 reads (28%) | catalogued as COSV53603382; called by muse, mutect2, varscan2
- IGHV3-73 | c.51C>T p.V17= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs1350952619; called by muse, mutect2, varscan2
- IGLV1-44 | c.177C>T p.L59= | Silent (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- IRX2 | c.1188G>A p.G396= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs148326536; called by mutect2, varscan2
- KCNA10 | c.795C>T p.T265= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV63905041; called by muse, mutect2, varscan2
- KCNIP4 | c.258G>A p.E86= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV62853915; called by muse, mutect2, varscan2
- KIF15 | c.3894G>A p.E1298= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as rs753132265, COSV58163218; called by muse, mutect2, varscan2
- KLHDC7A | c.840G>A p.G280= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV68770420; called by muse, varscan2
- KLHDC7A | c.909G>A p.Q303= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV68770425; called by muse, varscan2
- LOXL2 | c.285C>T p.V95= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs770873847, COSV66691450; called by mutect2, varscan2
- LPA | c.3156G>A p.Q1052= | Silent (SNP) | VAF 25/136 reads (18%) | called by muse, mutect2, varscan2
- MAP3K9 | c.3294C>T p.I1098= (on ENST00000554752 / NM_001284230.1; = p.I1112= on NM_033141.4) | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV67122231; called by muse, mutect2, varscan2
- MC4R | c.732G>A p.A244= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs770669384, COSV55352032; called by mutect2, varscan2
- MLF1 | c.132C>T p.I44= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV63034710; called by muse, mutect2, varscan2
- MMP1 | c.948C>T p.F316= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV59509464; called by mutect2, varscan2
- MOXD1 | c.1380C>T p.T460= | Silent (SNP) | VAF 41/132 reads (31%) | catalogued as COSV60946489; called by muse, mutect2, varscan2
- MRGPRD | c.879G>A p.G293= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs772140742, COSV58422829; called by mutect2, varscan2
- MRTFA | c.396C>T p.S132= | Silent (SNP) | VAF 44/262 reads (17%) | catalogued as rs536284634, COSV62935124; called by muse, mutect2, varscan2
- MUC16 | c.21288C>T p.L7096= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV67480284; called by mutect2, varscan2
- MYH1 | c.3435G>A p.R1145= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs548825820, COSV56853243; called by muse, mutect2, varscan2
- MYO3A | c.4791C>T p.Y1597= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs779121070, COSV52150643; called by mutect2, varscan2
- NFE2L3 | c.1572G>A p.R524= | Silent (SNP) | VAF 10/76 reads (13%) | called by mutect2, varscan2
- NRXN3 | c.2028A>G p.G676= (on ENST00000335750 / NM_001330195.2; = p.G303= on NM_004796.6) | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV59779674; called by muse, varscan2
- OR1L6 | c.231G>A p.V77= (on ENST00000373684; = p.V41= on NM_001004453.2) | Silent (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- OR4C13 | c.891G>A p.R297= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV73648695, COSV73648856; called by mutect2, varscan2
- OR8G1 | c.771C>T p.F257= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV58382145; called by mutect2, varscan2
- PAPPA2 | c.3204G>T p.V1068= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs1185895976, COSV62805123, COSV62807842; called by mutect2, varscan2
- PBX1 | c.366G>A p.K122= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs1318898046, COSV61537138, COSV61540256; called by muse, mutect2, varscan2
- PCARE | c.2772G>T p.L924= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV59054924, COSV59056318; called by mutect2, varscan2
- PCDHA4 | c.1353C>T p.N451= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs782636671, COSV63539191; called by mutect2, varscan2
- PCDHB2 | c.1218G>A p.V406= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV50599129; called by mutect2, varscan2
- PDE6B | c.234G>A p.K78= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- PLCH1 | c.4710C>T p.L1570= (on ENST00000340059 / NM_001130960.2; = p.L1562= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs773139178, COSV58204833; called by muse, mutect2, varscan2
- PLXNA4 | c.2742C>T p.I914= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs748905519, COSV58118238, COSV58145890; called by mutect2, varscan2
- POLD1 | c.723C>T p.F241= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs764364345, COSV70956464; ClinVar: likely benign; called by mutect2, varscan2
- POU2AF1 | c.396G>A p.T132= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs535533779, COSV67577516; called by mutect2, varscan2
- PRPS1L1 | c.885C>T p.I295= | Silent (SNP) | VAF 53/274 reads (19%) | catalogued as rs867343944, COSV72649967; called by muse, varscan2
- PTPRB | c.4716G>A p.K1572= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV54241302; called by muse, mutect2, varscan2
- PZP | c.3639G>A p.E1213= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV54365662; called by muse, mutect2, varscan2
- RFX7 | c.1899A>G p.Q633= (on ENST00000559447 / NM_001368074.1; = p.Q730= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs758855222, COSV57966584; called by muse, mutect2, varscan2
- RHOBTB2 | c.927G>A p.S309= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV52572340; called by muse, mutect2, varscan2
- RIF1 | c.2739C>T p.S913= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV54620881; called by muse, mutect2, varscan2
- S100A7L2 | c.264G>A p.K88= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV64195289; called by muse, mutect2, varscan2
- SAT2 | c.468C>T p.F156= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV52647418; called by muse, mutect2, varscan2
- SBNO2 | c.369C>T p.F123= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV62322099; called by muse, mutect2, varscan2
- SELENOP | c.459C>T p.F153= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs867134037, COSV62793337; called by muse, mutect2, varscan2
- SH3TC2 | c.2985G>A p.R995= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV60465897; called by muse, mutect2, varscan2
- SHC3 | c.1392C>T p.P464= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV65439661; called by muse, mutect2, varscan2
- SLC22A9 | c.1050G>A p.R350= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as COSV54168783; called by muse, mutect2, varscan2
- SLC52A1 | c.1320G>A p.K440= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV54692682, COSV54693463; called by muse, mutect2, varscan2
- SLC6A17 | c.1123C>T p.L375= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV58994990; called by muse, varscan2
- SLITRK1 | c.1314G>T p.L438= | Silent (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2
- SLX4IP | c.225C>G p.P75= | Silent (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- SNTG2 | c.675C>T p.S225= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV57996741; called by muse, mutect2, varscan2
- SPEN | c.5505C>T p.I1835= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs753572544, COSV65358429; called by mutect2, varscan2
- SPHKAP | c.5016C>T p.F1672= (on ENST00000392056 / NM_001142644.2; = p.F1643= on NM_030623.3) | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs61752219, COSV60887997; called by muse, mutect2, varscan2
- SPIN1 | c.342C>T p.L114= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as COSV65500425; called by muse, mutect2, varscan2
- SPRR1A | c.174G>A p.Q58= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV61081404; called by muse, mutect2
- SSH1 | c.1618C>T p.L540= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV58458385; called by muse, mutect2, varscan2
- ST18 | c.1536C>T p.F512= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs1397197089, COSV52487823; called by mutect2, varscan2
- STAB1 | c.7068G>A p.L2356= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs1331497344, COSV58740372; called by muse, mutect2, varscan2
- TACC1 | c.1033C>T p.L345= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV52526836; called by muse, mutect2, varscan2
- TAF1B | c.1482T>G p.L494= | Silent (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- TBC1D19 | c.354C>T p.I118= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV53519345; called by muse, mutect2, varscan2
- TBCEL | c.468C>T p.L156= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV52461205; called by mutect2, varscan2
- TBCK | c.1950G>A p.G650= (on ENST00000273980 / NM_001163436.4; = p.G587= on NM_033115.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV56759422; called by muse, varscan2
- TCF7L1 | c.1263G>A p.K421= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV56401045; called by muse, mutect2
- TEX11 | c.174G>A p.R58= (on ENST00000344304; = p.R43= on NM_031276.3) | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs1329390749, COSV60235110; called by muse, mutect2, varscan2
- TMEM131 | c.768C>T p.L256= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV51779677; called by muse, mutect2, varscan2
- TMIGD2 | c.444C>T p.F148= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV56667763; called by mutect2, varscan2
- TOR1A | c.330C>T p.F110= | Silent (SNP) | VAF 36/175 reads (21%) | catalogued as rs1293414901, COSV61028743; called by mutect2, varscan2
- TP53 | c.1023C>T p.F341= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs864622369, COSV52693704, COSV52845855, COSV99411018; ClinVar: likely benign; called by muse, varscan2
- TRHR | c.528G>A p.V176= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs867974653, COSV61234295; called by mutect2, varscan2
- UACA | c.2721A>G p.L907= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV59857873; called by muse, mutect2, varscan2
- UNC79 | c.7575C>T p.A2525= (on ENST00000393151 / NM_001346218.2; = p.A2348= on NM_020818.5) | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV56399811; called by muse, mutect2, varscan2
- UTP11 | c.369C>T p.L123= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV65951583; called by muse, mutect2, varscan2
- VCP | c.399A>G p.V133= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs772069942, COSV62721559; called by muse, varscan2
- WDR59 | c.1209G>A p.R403= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs773824746, COSV50938918; called by mutect2, varscan2
- Z83844.2 | c.1134C>G p.A378= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV60929075; called by muse, mutect2, varscan2
- ZNF613 | c.1245C>T p.L415= (on ENST00000293471 / NM_001031721.4; = p.L379= on NM_024840.4) | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV53273052; called by muse, mutect2, varscan2
- AGAP7P | n.1543C>T | RNA (SNP) | VAF 11/152 reads (7%) | called by muse, mutect2, varscan2
- AL133467.5 | chr14:95663548 C>T | 3'Flank (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- ATP11AUN | n.864G>A | RNA (SNP) | VAF 7/22 reads (32%) | called by mutect2, varscan2
- CFAP74 | c.2176+93G>A | Intron (SNP) | VAF 30/147 reads (20%) | catalogued as COSV54570711; called by muse, mutect2, varscan2
- LEKR1 | c.*1418C>T | 3'UTR (SNP) | VAF 10/58 reads (17%) | called by muse, varscan2
- LEKR1 | c.*1419C>T | 3'UTR (SNP) | VAF 10/57 reads (18%) | called by muse, varscan2
- MIR519D | n.24G>A | RNA (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- PSG5 | c.431-2961A>G | Intron (SNP) | VAF 37/148 reads (25%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23827T>G | Intron (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- ZNF99 | c.*716C>T | 3'UTR (SNP) | VAF 14/76 reads (18%) | catalogued as COSV68054629, COSV68055914; called by muse, varscan2
